Gene-level copy-number profile of tumor specimen C3N-03008-01 from CPTAC case C3N-03008, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.1 years (23,789 days).
Specimen C3N-03008-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 224fa012-fa37-492e-b9fc-5fdff131608a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03008-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/71034e22-27ac-44ec-b3cb-b8d620d9a781

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 157; copy number 2: 8,791; copy number 3: 14,444; copy number 4: 28,830; copy number 5: 731; copy number 6: 4,093; copy number 7: 896; copy number 8: 31; copy number 10: 246; copy number 13: 10; copy number 15: 6; copy number 16: 127; copy number 32: 22; copy number 41: 7; copy number 48: 6.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,614,419–68,628,899, 3 genes (within-gene range 0–1): AC147055.2, AC147055.4, AC147055.3.
- chr6:20,099,684–20,212,469, 1 gene (within-gene range 0–4): MBOAT1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–2): RNA5SP251.
- chr11:90,049,945–90,073,055, 4 genes: AP004607.2, AP004607.4, TRIM64EP, AP004607.5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 424 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:72,807,267–73,421,482, 10 genes, copy number 13: HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB.
- chr7:54,542,325–56,000,181, 41 genes, copy number 15–48: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17.
- chr11:65,745,729–71,818,238, 246 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr11:75,803,431–83,423,516, 127 genes, copy number 16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
